Somatic mutation profile of tumor specimen MMRF_2676_1_BM_CD138pos (aliquot MMRF_2676_1_BM_CD138pos_T1_KHS5U_L13794) from MMRF case MMRF_2676, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.3 years (17,278 days).
Specimen MMRF_2676_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4dadc81-df67-4710-bdc0-5352e99f8722.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2676_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2676_1_PB_WBC_C3_KHS5U_L13795; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eede8423-54de-4bc1-b50c-87c77ce651a3

The open-access MAF lists 124 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 22, Silent 19, Intron 12, 5'UTR 5, Nonsense Mutation 4, RNA 4, 5'Flank 3, Frame Shift Del 1, 3'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 166/354 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs149692828; called by muse, varscan2
- AXIN2 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs773033390; ClinVar: uncertain significance; called by muse, mutect2
- CAST | c.1667C>T p.P556L (on ENST00000341926; = p.P639L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 272/719 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs1239792416; called by muse, mutect2, varscan2
- CHST8 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 15/512 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as COSV99381120; called by muse, mutect2
- CLTC | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 74/149 reads (50%) | catalogued as COSV52247564; called by muse, mutect2, varscan2
- COL4A2 | c.3598G>A p.G1200S | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271683445; called by muse, mutect2, varscan2
- GLIPR1L2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 163/313 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs781325607, COSV100158334; called by muse, mutect2, varscan2
- IGHV1-69 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 258/267 reads (97%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1064565; called by muse, mutect2, varscan2
- IGLV4-69 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 238/255 reads (93%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs1383242104; called by muse, varscan2
- IGLV4-69 | c.197A>T p.Y66F | Missense Mutation (SNP) | VAF 131/142 reads (92%) | SIFT tolerated (0.4); PolyPhen benign (0.242); catalogued as rs566510459; called by muse, mutect2, varscan2
- IGLV4-69 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 102/111 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377104473; called by muse, mutect2, varscan2
- IPMK | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 152/287 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs772940182; called by muse, mutect2, varscan2
- LHCGR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs979633619, COSV54295551, COSV54300568; called by muse, mutect2, varscan2
- LIG3 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758686695, COSV52011297, COSV99252275; called by muse, mutect2, varscan2
- MADCAM1 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.029); catalogued as rs1386128272; called by muse, mutect2, varscan2
- PAPOLA | c.138G>C p.L46F | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53483429; called by muse, mutect2
- PAXIP1 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 171/183 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1416218358; called by muse, mutect2, varscan2
- PHYHIP | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs760499209, COSV58689352; called by muse, mutect2
- PKP4 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 66/123 reads (54%) | catalogued as rs771934822, COSV101081177, COSV67676038; called by muse, mutect2, varscan2
- RBM47 | c.1623C>A p.Y541* (on ENST00000295971 / NM_001098634.2; = p.Y472* on NM_019027.4) | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV55931321; called by muse, mutect2, varscan2
- RYR1 | c.5500G>A p.V1834M | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs1485656805; called by muse, mutect2
- TNXB | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1179436412, COSV64483049; called by muse, mutect2, varscan2
- UBE3A | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 150/332 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51666916; called by muse, mutect2, varscan2
- ZFP90 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 68/70 reads (97%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1432412133, COSV68051157; called by muse, mutect2, varscan2
- ZNF512B | c.2265C>T p.D755= | Splice Region (SNP) | VAF 59/113 reads (52%) | catalogued as rs766563949; called by muse, mutect2, varscan2
- ZNF816 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 130/358 reads (36%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.968); catalogued as rs150225613; called by muse, mutect2
- ABCC8 | c.4333T>G p.C1445G | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ADD1 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CENPF | c.916A>T p.K306* | Nonsense Mutation (SNP) | VAF 78/361 reads (22%) | called by muse, mutect2, varscan2
- CRYBG3 | c.3302A>C p.N1101T | Missense Mutation (SNP) | VAF 178/366 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- DMD | c.5025+1G>T p.X1675_splice | Splice Site (SNP) | VAF 153/155 reads (99%) | called by muse, mutect2, varscan2
- DNAH9 | c.11584A>G p.M3862V | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- EXOC4 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 118/232 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FMOD | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 125/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FPR3 | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 344/732 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- KRT3 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KRTAP4-16 | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- LATS2 | c.970G>C p.A324P | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- LRRC49 | c.1688T>G p.I563S | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- MAP3K1 | c.3541A>G p.M1181V | Missense Mutation (SNP) | VAF 21/403 reads (5%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.824); called by muse, mutect2
- MTA1 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 207/222 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- MUCL3 | c.1369G>A p.V457M (on ENST00000304311; = p.V1333M on NM_080870.4) | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NETO1 | c.1440C>A p.H480Q | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NUP153 | c.1614T>A p.N538K | Missense Mutation (SNP) | VAF 74/80 reads (93%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHF8 | c.1795G>A p.D599N (on ENST00000357988 / NM_001184896.1; = p.D563N on NM_015107.3) | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.239); called by muse, mutect2
- POLR2A | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 206/461 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1CA | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 165/305 reads (54%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRDM1 | c.2193_2194del p.K732Vfs*2 | Frame Shift Del (DEL) | VAF 168/246 reads (68%) | called by pindel, varscan2
- RBL1 | c.1607T>C p.V536A | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- RBM47 | c.862T>G p.F288V | Missense Mutation (SNP) | VAF 115/158 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RC3H1 | c.3392C>G p.S1131C | Missense Mutation (SNP) | VAF 245/867 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- RIMBP2 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCIN | c.1342G>A p.D448N (on ENST00000297029 / NM_001112706.3; = p.D201N on NM_033128.3) | Missense Mutation (SNP) | VAF 136/330 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN4A | c.3928A>T p.I1310F | Missense Mutation (SNP) | VAF 121/232 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TADA2B | c.1237G>A p.G413S | Missense Mutation (SNP) | VAF 121/395 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM163 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 139/259 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK1 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZFHX4 | c.8474G>T p.S2825I | Missense Mutation (SNP) | VAF 175/363 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- COBL | c.2805T>C p.T935= | Silent (SNP) | VAF 189/433 reads (44%) | called by muse, mutect2, varscan2
- CYP2E1 | c.1257A>G p.G419= | Silent (SNP) | VAF 95/256 reads (37%) | catalogued as rs1460037447; called by muse, mutect2, varscan2
- DNAH7 | c.10233A>G p.E3411= | Silent (SNP) | VAF 105/256 reads (41%) | catalogued as COSV56764525; called by muse, mutect2, varscan2
- IGHV2-70 | c.282C>T p.T94= | Silent (SNP) | VAF 69/86 reads (80%) | catalogued as rs368464634; called by muse, varscan2
- IGLV4-69 | c.288C>T p.Y96= | Silent (SNP) | VAF 101/110 reads (92%) | catalogued as rs1201329400; called by muse, mutect2, varscan2
- JAG1 | c.2199C>T p.G733= | Silent (SNP) | VAF 77/253 reads (30%) | catalogued as rs756062969, COSV99653569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1217 | c.1032C>T p.A344= | Silent (SNP) | VAF 170/469 reads (36%) | called by muse, mutect2, varscan2
- KIF26A | c.1785C>T p.G595= | Silent (SNP) | VAF 97/109 reads (89%) | catalogued as rs749215151; called by muse, mutect2, varscan2
- LIPC | c.1299C>T p.V433= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- MS4A18 | c.63C>T p.H21= | Silent (SNP) | VAF 91/203 reads (45%) | catalogued as rs1315035604; called by muse, mutect2, varscan2
- MYH13 | c.4761C>T p.I1587= | Silent (SNP) | VAF 87/190 reads (46%) | catalogued as COSV52822481; called by muse, mutect2, varscan2
- NPC1L1 | c.3885C>T p.D1295= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as rs376519611; called by muse, mutect2, varscan2
- PIWIL4 | c.2412C>T p.F804= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs752573443; called by muse, mutect2, varscan2
- PON2 | c.64C>T p.L22= | Silent (SNP) | VAF 17/187 reads (9%) | called by muse, mutect2
- RIMBP2 | c.72C>A p.A24= | Silent (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- STK32B | c.322C>T p.L108= | Silent (SNP) | VAF 68/157 reads (43%) | catalogued as rs1277221634; called by muse, mutect2, varscan2
- SVOPL | c.1212G>A p.L404= (on ENST00000419765; = p.L252= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 126/299 reads (42%) | called by muse, mutect2, varscan2
- TMEM115 | c.411C>T p.G137= | Silent (SNP) | VAF 154/279 reads (55%) | called by muse, mutect2, varscan2
- USH2A | c.11325C>T p.I3775= | Silent (SNP) | VAF 12/183 reads (7%) | catalogued as COSV56406459; called by muse, mutect2
- ANKRA2 | c.-26T>A | 5'UTR (SNP) | VAF 14/315 reads (4%) | called by muse, mutect2
- BTG2 | c.*1964_*1966del | 3'UTR (DEL) | VAF 57/267 reads (21%) | called by pindel, varscan2
- C1orf21 | c.*8593G>A | 3'UTR (SNP) | VAF 46/126 reads (37%) | catalogued as rs1023525805; called by muse, mutect2, varscan2
- CDNF | c.*195G>A | 3'UTR (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- CHRM1 | c.*775T>A | 3'UTR (SNP) | VAF 89/195 reads (46%) | called by muse, mutect2, varscan2
- COX11 | chr17:54968687 A>C | 5'Flank (SNP) | VAF 127/302 reads (42%) | catalogued as rs757731364; called by muse, mutect2, varscan2
- CPLX4 | c.*938C>T | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- DAPK1 | c.1825-208T>C | Intron (SNP) | VAF 28/84 reads (33%) | called by mutect2, varscan2
- DNAJB9 | c.*41C>T | 3'UTR (SNP) | VAF 216/532 reads (41%) | catalogued as rs1280745078; called by muse, mutect2, varscan2
- FAM183A | c.297+29C>T | Intron (SNP) | VAF 135/144 reads (94%) | catalogued as rs1420458051; called by muse, mutect2, varscan2
- FP565260.6 | c.*2273A>G | 3'UTR (SNP) | VAF 4/41 reads (10%) | catalogued as rs1466789100; called by muse, mutect2
- GALNT10 | c.1056+2772G>A | Intron (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- GPAT2P1 | n.75G>A | RNA (SNP) | VAF 42/63 reads (67%) | called by muse, mutect2, varscan2
- HGSNAT | c.1464+40T>C | Intron (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- IGSF10 | c.*1208G>A | 3'UTR (SNP) | VAF 75/193 reads (39%) | called by muse, mutect2, varscan2
- INPP4A | c.*1886G>A | 3'UTR (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- ITGA4 | c.556+800C>A | Intron (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- KAZN | c.-770G>T | 5'UTR (SNP) | VAF 130/167 reads (78%) | called by muse, mutect2, varscan2
- LRRC18 | c.*217G>A | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- LSM8 | c.31+224C>T | Intron (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- MFSD6 | c.*1234A>G | 3'UTR (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851378 T>G | 5'Flank (SNP) | VAF 119/121 reads (98%) | catalogued as rs1262641008; called by muse, mutect2, varscan2
- MTCL1 | c.2967+169G>C | Intron (SNP) | VAF 39/544 reads (7%) | called by muse, mutect2
- NAGLU | chr17:42547397 C>T | 3'Flank (SNP) | VAF 40/110 reads (36%) | catalogued as rs61747762; called by muse, mutect2, varscan2
- NT5M | c.*55C>T | 3'UTR (SNP) | VAF 33/106 reads (31%) | catalogued as rs777157439; called by muse, mutect2, varscan2
- PPP1R16B | c.*371A>C | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- PRR16 | c.*20T>A | 3'UTR (SNP) | VAF 170/448 reads (38%) | called by muse, mutect2, varscan2
- PSMC3 | c.75+31A>G | Intron (SNP) | VAF 68/127 reads (54%) | called by muse, mutect2, varscan2
- RARRES1 | c.*496G>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- RARRES2P6 | n.138C>A | RNA (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- RNF125 | c.*879A>G | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- RPS15 | c.3+50C>T | Intron (SNP) | VAF 34/830 reads (4%) | called by muse, mutect2
- SDF4 | c.557-1862dup | Intron (INS) | VAF 51/55 reads (93%) | catalogued as rs1467992314; called by mutect2, varscan2
- SLC29A4 | c.*468T>C | 3'UTR (SNP) | VAF 67/142 reads (47%) | called by muse, mutect2, varscan2
- SLC6A1 | c.*1935A>T | 3'UTR (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- SLC6A15 | c.-18T>G | 5'UTR (SNP) | VAF 34/76 reads (45%) | called by mutect2, varscan2
- SSPOP | n.12839C>T | RNA (SNP) | VAF 51/99 reads (52%) | catalogued as rs563749259, COSV100948076; called by muse, mutect2, varscan2
- TAAR3P | n.581T>G | RNA (SNP) | VAF 146/156 reads (94%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 168/331 reads (51%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
- TCP1 | c.-54G>C | 5'UTR (SNP) | VAF 125/134 reads (93%) | called by muse, mutect2, varscan2
- TRIM8 | c.*941C>G | 3'UTR (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866207 del CTGTAATTTTAATA | 5'Flank (DEL) | VAF 23/111 reads (21%) | called by mutect2, pindel, varscan2
- ZBTB44 | c.*347T>C | 3'UTR (SNP) | VAF 77/145 reads (53%) | called by muse, mutect2, varscan2
- ZNF20 | c.4-1146T>G | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- ZNF525 | c.*440G>A | 3'UTR (SNP) | VAF 18/428 reads (4%) | called by muse, mutect2
- ZNF664 | c.*339G>C | 3'UTR (SNP) | VAF 97/432 reads (22%) | called by muse, mutect2, varscan2
- ZYX | c.1023+889G>A | Intron (SNP) | VAF 292/621 reads (47%) | called by muse, mutect2, varscan2
